Somatic mutation profile of tumor specimen TCGA-AB-2885-03A (aliquot TCGA-AB-2885-03A-01W-0732-08) from TCGA case TCGA-AB-2885, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.7 years (26,176 days).
Specimen TCGA-AB-2885-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97386b4c-72d8-4828-8d12-c124f10d39a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2885-11A (Solid Tissue Normal), aliquot TCGA-AB-2885-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9685970-3091-48b9-b165-3682ac35bb0f

The open-access MAF lists 16 somatic variants for this specimen: 16 protein-altering or splice-affecting.
By variant classification: Missense Mutation 16.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507509, CD041931, CM021126, CX060726, COSV100692385, COSV61005028, COSV61006397; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 77/93 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs765803411, COSV52471978, COSV52475965, COSV99324572; called by mutect2, varscan2
- BSN | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56525323; called by muse, mutect2, varscan2
- CASKIN2 | c.3430G>A p.A1144T | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV58599070; called by muse, mutect2, varscan2
- DOK7 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as rs571769859, CM108746, COSV60773455; called by muse, mutect2, varscan2
- ITGA10 | c.3349C>T p.R1117W | Missense Mutation (SNP) | VAF 111/305 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs140404631; called by muse, mutect2, varscan2
- LEPR | c.3254T>A p.I1085N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.296); catalogued as COSV100848321; called by muse, mutect2
- LRP1B | c.5758G>A p.E1920K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV67261141; called by muse, mutect2, varscan2
- MRE11 | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV60579264; called by muse, mutect2, varscan2
- MTMR8 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs756598274, COSV66392809; called by muse, mutect2, varscan2
- PTPRT | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 115/306 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as rs762809890, COSV61963213, COSV62009649; called by muse, mutect2, varscan2
- RBM48 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV50403629; called by muse, varscan2
- RFX3 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.174); catalogued as COSV56523019; called by muse, mutect2, varscan2
- STRIP2 | c.544T>C p.C182R | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); catalogued as COSV50807315; called by muse, mutect2, varscan2
- XIRP2 | c.8977G>A p.A2993T (on ENST00000628543; = p.A3168T on NM_152381.6) | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1345897819, COSV54726684; called by muse, mutect2, varscan2
